Somatic mutation profile of tumor specimen TARGET-30-PARVWL-01A (aliquot TARGET-30-PARVWL-01A-01D) from TARGET case TARGET-30-PARVWL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,268 days).
Specimen TARGET-30-PARVWL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72326c55-7215-473f-9fa6-157dd341a040.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARVWL-10A (Blood Derived Normal), aliquot TARGET-30-PARVWL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d579468-cb91-4fc6-af28-4208f6a8bb75

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4433G>A p.R1478H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs756061989, COSV54334553; called by muse, mutect2, varscan2
- TRRAP | c.3991G>C p.E1331Q | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV62857305; called by muse, mutect2, varscan2
- STAG2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RELN | c.3447A>G p.R1149= | Silent (SNP) | VAF 6/172 reads (3%) | called by muse, mutect2
- XPO5 | c.*197G>T | 3'UTR (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
